Gene-level copy-number profile of tumor specimen C3L-05601-04 from CPTAC case C3L-05601, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.6 years (27,616 days).
Specimen C3L-05601-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a0546d56-fe4e-4f26-917e-d03f00d4341c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05601-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/3aed154b-f3b1-4cdb-aa3b-a9a98cc1751e

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 505; copy number 1: 33,373; copy number 2: 17,968; copy number 3: 5,453; copy number 4: 1,444; copy number 5: 19; copy number 11: 43; copy number 12: 55; copy number 22: 48.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,819,731–196,959,622, 4 genes (within-gene range 0–3): CFHR1, BX248415.1, CFHR4, CFHR2.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr18:79,069,285–80,247,514, 36 genes: ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 7,062 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,409,565–31,644,896, 10 genes, copy number 3 (within-gene range 1–3): SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1.
- chr1:143,419,625–196,795,407, 1,390 genes, copy number 3 (broad region; genes not listed).
- chr1:196,970,495–248,937,043, 1,130 genes, copy number 3 (broad region; genes not listed).
- chr2:42,826,322–43,132,482, 6 genes, copy number 3: CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580.
- chr2:109,129,205–109,504,634, 1 gene, copy number 3 (within-gene range 2–3): SH3RF3.
- chr2:109,251,422–113,052,867, 108 genes, copy number 3 (broad region; genes not listed).
- chr3:185,162,871–185,281,990, 4 genes, copy number 3: EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588.
- chr6:60,281,444–60,546,660, 1 gene, copy number 3: AC244258.1.
- chr7:37,032–3,174,654, 79 genes, copy number 3 (broad region; genes not listed).
- chr7:4,797,055–8,752,961, 109 genes, copy number 3–4 (broad region; genes not listed).
- chr7:21,215,537–23,832,513, 50 genes, copy number 3–4: RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7.
- chr7:24,537,332–28,180,795, 94 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:28,953,358–30,412,502, 39 genes, copy number 3–4: TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176.
- chr7:33,904,308–38,631,420, 92 genes, copy number 3–4 (broad region; genes not listed).
- chr7:43,112,629–44,986,961, 64 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:76,959,835–77,043,775, 1 gene, copy number 3 (within-gene range 2–3): DTX2P1-UPK3BP1-PMS2P11.
- chr7:76,978,617–77,032,361, 5 genes, copy number 3 (within-gene range 2–3): DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.
- chr7:83,663,419–84,584,322, 4 genes, copy number 3: RAD23BP2, SEMA3A, RPL7P30, AC003984.1.
- chr7:86,876,906–102,690,469, 375 genes, copy number 3–4 (broad region; genes not listed).
- chr7:138,298,088–138,799,560, 11 genes, copy number 3 (within-gene range 2–3): AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4.
- chr7:141,656,728–141,702,166, 1 gene, copy number 3 (within-gene range 2–3): DENND11.
- chr7:141,704,003–148,963,410, 229 genes, copy number 3–4 (broad region; genes not listed).
- chr7:149,398,204–159,233,377, 199 genes, copy number 3 (broad region; genes not listed).
- chr8:60,046,755–60,281,400, 3 genes, copy number 4: AC021393.1, SLC2A13P1, CA8.
- chr8:98,371,228–103,332,866, 128 genes, copy number 3 (broad region; genes not listed).
- chr8:125,430,358–130,017,129, 61 genes, copy number 3 (broad region; genes not listed).
- chr10:49,818,279–50,152,287, 12 genes, copy number 3: PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1.
- chr13:18,467,172–109,401,641, 1,221 genes, copy number 3 (broad region; genes not listed).
- chr14:30,370,108–32,837,684, 51 genes, copy number 3: AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr14:106,482,435–106,521,073, 7 genes, copy number 3 (within-gene range 2–3): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,556,936–106,879,812, 51 genes, copy number 3: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:16,499,533–16,762,465, 3 genes, copy number 3: AC136431.1, AC136619.2, AC092326.1.
- chr16:46,469,341–46,931,289, 18 genes, copy number 3: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr17:26,981,694–34,726,170, 344 genes, copy number 3–4 (broad region; genes not listed).
- chr17:36,116,177–41,668,031, 269 genes, copy number 3–22 (broad region; genes not listed).
- chr20:25,985,210–64,327,972, 881 genes, copy number 4–5 (broad region; genes not listed).
- chr21:10,482,738–13,120,807, 11 genes, copy number 3 (within-gene range 2–3): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 32,468. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
